Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A3Y1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A3Y1-01A (Primary Tumor).

Procurement Date Laterality:Tumor Features: Unknown, Tumor Extent: Superficial muscle (inner half), Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Path Report:BLADDER TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Bladder

Tumor size: 3 x 2.5 x 5 cm

Tumor features: Papillary

Histologic type: Transitional cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Superficial muscle (inner half) ✓

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
carcinoma, urothelial, NOS
8120/3
Site: bladder, NOS
C67.9 u/6/12
RO

Source: NCI Genomic Data Commons file 70e4144d-8e8d-4a82-999a-b5f4c9c4d40b (TCGA-E7-A3Y1.015FB5A9-F21F-48CC-9EDA-43952CE358B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).